Somatic mutation profile of tumor specimen TCGA-24-1434-01A (aliquot TCGA-24-1434-01A-01W-0545-08) from TCGA case TCGA-24-1434, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.7 years (21,810 days).
Specimen TCGA-24-1434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 877b8ce5-ea5c-4c88-8d7a-ad2f9083f690.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1434-10A (Blood Derived Normal), aliquot TCGA-24-1434-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0749d749-f9b3-4a9d-b573-0068fd33f769

The open-access MAF lists 68 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 15, Frame Shift Del 4, Frame Shift Ins 3, Nonsense Mutation 2, Intron 1, Splice Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP5Z1 | c.438G>C p.E146D | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.162); catalogued as COSV100804276, COSV62242983; called by muse, mutect2, varscan2
- AQR | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 24/389 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99332922, COSV99334406; called by muse, mutect2
- ATP5MC2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs374457649; called by muse, mutect2, varscan2
- CA6 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 36/984 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV66263315; called by muse, mutect2
- CD86 | c.403A>C p.N135H (on ENST00000330540 / NM_175862.5; = p.N129H on NM_006889.4) | Missense Mutation (SNP) | VAF 101/623 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV52608972; called by muse, mutect2, varscan2
- CRACR2A | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 186/376 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs928597030, COSV99364395; called by muse, mutect2, varscan2
- CRY1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV50487640; called by muse, mutect2, varscan2
- DGKZ | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1465025057, COSV58992764; called by muse, mutect2, varscan2
- DNAH10 | c.2033A>G p.E678G (on ENST00000409039; = p.E617G on NM_207437.3) | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV68998662; called by muse, mutect2, varscan2
- DNM2 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs778020908, COSV58968501; called by muse, mutect2, varscan2
- DOCK3 | c.5291G>A p.R1764Q | Missense Mutation (SNP) | VAF 99/204 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs375984390, COSV56539322; called by muse, mutect2, varscan2
- DOCK9 | c.5854G>C p.D1952H (on ENST00000376460 / NM_001366676.2; = p.D1953H on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59638436; called by muse, mutect2, varscan2
- DPPA4 | c.437A>C p.Q146P | Missense Mutation (SNP) | VAF 51/311 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100169114, COSV59509112; called by muse, mutect2, varscan2
- EPHA7 | c.617G>T p.W206L | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV65170077; called by muse, mutect2, varscan2
- EXPH5 | c.4274C>T p.S1425F | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.132); catalogued as COSV56206158; called by muse, mutect2, varscan2
- FLG | c.4699C>T p.R1567W | Missense Mutation (SNP) | VAF 180/334 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as rs529239965, COSV100911363, COSV64240848, COSV64245693; called by muse, mutect2, varscan2
- FLG | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.586); catalogued as COSV64241707, COSV64244634, COSV64245696; called by muse, mutect2, varscan2
- FOXM1 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145831539; called by muse, mutect2, varscan2
- IGHV1-24 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 291/1026 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs781997774; called by muse, mutect2, varscan2
- IL4R | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV50158432; called by muse, mutect2, varscan2
- KCND3 | c.1817A>G p.K606R | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.065); catalogued as COSV100136573; called by muse, mutect2, varscan2
- KIAA1109 | c.5231C>T p.T1744M | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs777875424, COSV52685911; called by muse, mutect2, varscan2
- KMT2E | c.4771C>G p.P1591A | Missense Mutation (SNP) | VAF 56/416 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV57577482; called by muse, mutect2, varscan2
- MFN1 | c.1982C>T p.T661M | Missense Mutation (SNP) | VAF 57/409 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs767599419, COSV54940584; called by muse, varscan2
- MITD1 | c.611T>C p.M204T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV56806827; called by muse, mutect2
- MVP | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs748570854, COSV62422998; called by muse, varscan2
- NUP188 | c.3351+1G>T p.X1117_splice | Splice Site (SNP) | VAF 26/730 reads (4%) | catalogued as COSV101001108; called by muse, mutect2
- NUP188 | c.3586C>T p.Q1196* | Nonsense Mutation (SNP) | VAF 62/874 reads (7%) | catalogued as COSV101001109; called by muse, mutect2
- OR4K13 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.074); catalogued as COSV59860317; called by muse, mutect2, varscan2
- PCDHB4 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52025265; called by muse, mutect2, varscan2
- PLXDC2 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs759906707, COSV65920567, COSV65922865; called by muse, mutect2, varscan2
- PSG1 | c.532T>A p.Y178N | Missense Mutation (SNP) | VAF 411/1416 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54954502; called by muse, mutect2, varscan2
- RFPL1 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 54/1505 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV100585549; called by muse, mutect2
- RGS7 | c.855T>A p.S285R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.653); catalogued as COSV58553990, COSV58556587; called by muse, mutect2, varscan2
- RNF17 | c.1590A>T p.G530= | Splice Region (SNP) | VAF 34/187 reads (18%) | catalogued as COSV55047072; called by muse, mutect2, varscan2
- SBF1 | c.2744dup p.S916Qfs*11 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs781322321; called by pindel, varscan2
- SHC1 | c.92dup p.E32Gfs*23 | Frame Shift Ins (INS) | VAF 20/163 reads (12%) | catalogued as rs752843778; called by mutect2, varscan2
- SPICE1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV55623586; called by muse, mutect2, varscan2
- TAS2R1 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 56/155 reads (36%) | catalogued as COSV66779153; called by muse, mutect2, varscan2
- TP53 | c.1032del p.N345Mfs*25 | Frame Shift Del (DEL) | VAF 148/281 reads (53%) | catalogued as COSV53388115, COSV53846847; called by mutect2, pindel, varscan2
- TTBK1 | c.3194C>G p.T1065R | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV52494789; called by muse, mutect2, varscan2
- TTN | c.12982C>A p.P4328T (on ENST00000591111; = p.P4282T on NM_003319.4) | Missense Mutation (SNP) | VAF 24/849 reads (3%) | catalogued as COSV60166934; called by muse, mutect2
- VCAN | c.8549C>A p.P2850Q | Missense Mutation (SNP) | VAF 15/375 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV99424179; called by muse, mutect2
- ZNF169 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs774957018, COSV61765748; called by muse, mutect2, varscan2
- ZNF605 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV59159855; called by muse, mutect2, varscan2
- ZNF80 | c.403T>G p.C135G | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57362083; called by muse, mutect2, varscan2
- ACTRT2 | c.633del p.L212Sfs*28 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- CYP2C19 | c.1260del p.S422Vfs*28 | Frame Shift Del (DEL) | VAF 152/633 reads (24%) | called by mutect2, pindel, varscan2
- IGKV2D-24 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 74/321 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- KDM5C | c.1688dup p.L564Pfs*58 | Frame Shift Ins (INS) | VAF 321/878 reads (37%) | called by mutect2, pindel, varscan2
- MARK3 | c.134_136del p.S45del | In Frame Del (DEL) | VAF 126/513 reads (25%) | called by pindel, varscan2
- TTK | c.1030_1031del p.K344Efs*3 | Frame Shift Del (DEL) | VAF 29/144 reads (20%) | called by mutect2, pindel, varscan2
- C5AR2 | c.447C>T p.C149= | Silent (SNP) | VAF 5/106 reads (5%) | catalogued as rs1424717231, COSV57255754; called by muse, mutect2
- COL6A2 | c.1974G>A p.T658= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs760131219, COSV55997906; called by muse, mutect2, varscan2
- CPLX2 | c.315C>T p.C105= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as rs1414498178, COSV64000441; called by muse, mutect2, varscan2
- DDX51 | c.660C>A p.S220= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV57959376; called by muse, mutect2
- GDPD5 | c.711C>G p.P237= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV61129354; called by muse, mutect2, varscan2
- GMPR | c.372G>A p.K124= | Silent (SNP) | VAF 40/1038 reads (4%) | catalogued as COSV99439619; called by muse, mutect2
- KCNN1 | c.462G>T p.L154= | Silent (SNP) | VAF 57/144 reads (40%) | catalogued as COSV55840821; called by muse, mutect2, varscan2
- KRTAP5-7 | c.258C>T p.G86= | Silent (SNP) | VAF 32/290 reads (11%) | catalogued as COSV68325490; called by muse, varscan2
- PCDH9 | c.3273C>T p.D1091= (on ENST00000377865 / NM_203487.3; = p.D1057= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/333 reads (19%) | catalogued as rs372281341; called by muse, mutect2, varscan2
- RPS6 | c.183C>T p.F61= | Silent (SNP) | VAF 30/336 reads (9%) | catalogued as rs766566379, COSV59548250; called by muse, mutect2
- SIDT1 | c.1548G>A p.L516= | Silent (SNP) | VAF 154/900 reads (17%) | catalogued as COSV53504960; called by muse, mutect2, varscan2
- SVEP1 | c.6390G>A p.G2130= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV99927954; called by muse, mutect2, varscan2
- SYT8 | c.1005G>T p.L335= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV53290630; called by muse, mutect2
- TAP2 | c.696C>A p.S232= | Silent (SNP) | VAF 133/471 reads (28%) | catalogued as COSV66500531; called by muse, mutect2, varscan2
- ZAN | c.4599C>T p.G1533= | Silent (SNP) | VAF 43/55 reads (78%) | catalogued as COSV61812954; called by muse, mutect2, varscan2
- TTN | c.10361-5391A>C | Intron (SNP) | VAF 64/337 reads (19%) | catalogued as COSV60237718; called by muse, mutect2, varscan2
